Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A1Z3, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A1Z3-06A (Metastatic).

Prof.Dr.

ICD-0-3

Melanoma, NOS 8720/3

Site: skin, NOS C44.9

ju 7/24/11

Patient: XXXX
geb. *** **

Datum:

Translation of pathology report F

Sample

Gross Pathology

Cryofixed specimen with a weight of

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 90 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine. There is a high nucleo/cytoplasmatic ratio. The mitotic count is 6 mitoses per square millimetre. The tumor cells have a middle sized cytoplasm. The tumor shows a nest like growth pattern. Lymphocytic infiltrates compound approx. 3 percent of the tissue cells.

Diagnosis: Parts of a malignat tumor, consistent with a metastasis of a melanoma.

Dr.

CQLF site = skin, NOS

HPA Discrepancy		

Source: NCI Genomic Data Commons file d7d21302-8dc9-4881-905a-54e86173a7f5 (TCGA-FS-A1Z3.6C91D798-AA14-4566-BDA1-DA3E639A76E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).